Surgical pathology report (de-identified scan), TCGA case TCGA-23-1030, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1030-01A (Primary Tumor).

[page 1 of 6]
Path #:

SURGICAL PATHOLOGY REPORT

SPECIMEN(S) SUBMITTED: A. OMENTUM FS, B. LEFT ADNEXA FS, C. RIGHT ADNEXA, D. UTERUS, E. LEFT SIDE WALL TUMOR, F. FALCIFORM, G. OMENTUM #2, H. DISTAL PANCREATECTOMY, I. SEGMENT TRANSVERSE COLON RESECTION, J. ILEOCECAL VALVE, K. RECTOSIGMOID EPLOICA

DIAGNOSIS:

A. OMENTUM, PARTIAL OMENTECTOMY:

- Metastatic papillary serous carcinoma (see comment)

B. ADNEXA, LEFT, SALPINGO-OOPHORECTOMY:

- Primary ovarian papillary serous carcinoma, grade 3 (see comment)
- Tumor extensively involves ovary and also involves ovarian serosal surface
- Secondary involvement of adnexal soft tissues (ligaments) by carcinoma is present
- Lymphovascular invasion by carcinoma is present
- Focal serosal involvement of fallopian tube by metastatic carcinoma
- Ovary also shows atrophic changes with relative cortical stromal hyperplasia and associated hyperthecosis (focally nodular) cystic epithelial inclusions, foreign body giant cell reactive and serosal adhesions
- Tubo-ovarian adhesions
- Paratubal cyst lined by benign serous epithelium (hydatid of Morgagni)
- Paratubal wolffian duct remnants

C. ADNEXA, RIGHT, SALPINGO-OOPHORECTOMY:

- Primary ovarian papillary serous carcinoma, grade 3 (see comment)
- Tumor subtotally replaces ovary and also involves ovarian serosal surface
- Carcinoma also involves paraovarian ligamentous adnexal soft tissues
- Lymphovascular invasion by carcinoma is present
- No evidence of metastatic carcinoma involving fallopian tube
- Ovary also shows cystic epithelial inclusions, atrophic changes and serosal adhesions
- Paraovarian/paratubal cyst lined by benign serous epithelium (hydatid of Morgagni)
- Paraovarian/paratubal endosalpingiosis
- Paratubal wolffian duct remnants

D. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:

- Metastatic serous papillary carcinoma involving vaginal wall (muscular wall of vaginal cuff), regional (paravaginal lymphovascular spaces), and extensively involving paravaginal soft tissues (slides D11 and D12)
- Metastatic papillary serous carcinoma and associated psammoma body also involves right parametrial soft tissues
- Left parametrial soft tissues are free of tumor

[page 2 of 6]
PATH #:

- Uterus with inactive (atrophic to weakly proliferative) endometrium with foci of ciliated epithelial metaplasia, a few cystically dilated endometrial glands, and reactive lymphoid aggregates in the endometrial stroma
- Cervix with atrophic squamous changes, chronic and minimal acute inflammation, squamous metaplasia, cystic endocervical tunnel clusters, and nabothian cysts
- No evidence of metastatic carcinoma involving uterus or uterine cervix

E. SOFT TISSUE, LEFT [PELVIC] SIDEWALL "TUMOR", EXCISION:

- Metastatic papillary serous carcinoma (see comment)

F. SOFT TISSUE, FALCIFORM [LIGAMENT], EXCISION:

- No evidence of metastatic carcinoma

G. OMENTUM, "SECOND SPECIMEN", PARTIAL OMENTECTOMY:

- Metastatic papillary serous carcinoma extensively involving omentum, involving regional lymphovascular spaces, and involving one of one omental lymph node (1/1)
- Omentum also shows recent hemorrhages, adherent blood clot, adhesions, and reactive mesothelium proliferation

H. PANCREAS AND SPLEEN, DISTAL PANCREATECTOMY (EN BLOC RESECTION OF DISTAL PANCREAS AND ADJACENT SPLEEN):

- Metastatic papillary serous carcinoma extensively involving the peripancreatic and perisplenic soft tissues and regional lymphovascular spaces
- No invasion of spleen or pancreas by carcinoma
- Two small reactive peripancreatic lymph nodes are negative for metastatic carcinoma
- Pancreas also shows focal atrophic changes and fibrosis

I. COLON, TRANSVERSE, SEGMENTAL RESECTIONS:

- Two segments of large intestine
- Longer segment of large intestine with attached pericolic/mesenteric fat shows extensive involvement of serosa and pericolic tissues by metastatic serous papillary carcinoma
- Metastatic carcinoma in the longer intestinal segment also involves the muscular wall of the longer segment
- No evidence of metastatic carcinoma at proximal or distal margins of longer intestinal segment
- One pericolic lymph node attached to longer segment is negative for metastatic carcinoma (0/1)
- Shorter segment of colon with microscopic foci of metastatic serous carcinoma involving serosa/subserosa and regional lymphatics

J. SMALL AND LARGE INTESTINE, TERMINAL ILEUM AND RIGHT HEMICOLECTOMY:

- Metastatic papillary serous carcinoma extensively involving pericolic fat/mesentery attached to right colon; some nodular aggregates of tumor in the pericolic fat might possibly represent former lymph nodes now totally replaced by metastatic carcinoma; however, no residual normal lymph node tissue is identified
- No involvement of intestinal tissues (terminal ileum, ileocecal valve, or right colon) by carcinoma
- No evidence of tumor at proximal or distal margins of the segmental resection specimen

K. EPIPLOICA ATTACHED TO RECTOSIGMOID COLON, EXCISION:

[page 3 of 6]
PATH #:

- **Metastatic serous carcinoma (see comment)**

COMMENT: The tumor in all involved sites exhibits features of high-grade serous carcinoma. Growth patterns include papillary, cystic, solid, and glandular. Tumor-associated psammoma bodies are present in most of the involved sites. Lymphovascular invasion by carcinoma is present virtually in all of the involved sites. Tumor-associated necrosis, secondary acute and chronic inflammatory changes and fibrosis are present. Adhesions and secondary reactive mesothelial changes are also present in the vicinity of tumor in many of the involved sites. The preliminary pathologic findings were discussed with

HISTORY: Ovarian cancer

MICROSCOPIC:
See diagnosis.

SPECIAL STUDIES: Photograph (H); H&E-stained step sections (D1 x1, D3 x1, D4 x1, D13 x1, I2 x2, I3 x2, J3 x1, J4 x1, J5 x1)

IMMUNOSTAINS: None

GROSS:

A. OMENTUM FS

Labeled with the patient's name, labeled "omentum - FS", received fresh in the Operating Room for intraoperative frozen section, is a 19.5 x 8.0 x 4.0 cm portion of lobulated yellow omental fat that is partially replaced by multiple nodular and plaque-like aggregates of firm tan-white metastatic tumor. The individual tumor deposits range from about 0.3 to 4.0 cm in maximum dimension. Adhesions and scant adherent blood clot are also noted. A representative portion of the omentum with tumor was frozen and sectioned for intraoperative diagnosis (FS #1). Frozen section interpretation was rendered by . The frozen section remnant and the rest of the specimen are subsequently fixed in formalin. Representative sections submitted.

A1. Remnant of frozen section #1 - 1

A2. Unfrozen omentum with tumor - 2

B. LEFT ADNEXA FS

Labeled with the patient's name, labeled "left adnexa - FS", and received fresh in the Operating Room for intraoperative frozen section is a salpingo-oophorectomy specimen. The ovary measures about 5.5 x 3.0 x 2.0 cm. The external surface of the ovary is partially coated by nodular and plaque-like deposits of tan tumor, some of which are papillated soft and friable and others are firmer and nodular. There is also a 1.5 cm in diameter paraovarian/paratubal cyst that is thin-walled and contains clear pale yellow fluid that is adherent to both the ovary and adjacent fallopian tubes. Cut sections of the ovary subtotal replacement by tan tumor. Several corpora albicantia and a few minute cystic spaces are also noted in the ovary. Tumor-associated necrosis is present focally. The adjacent fallopian tube has fimbria at one end, is adherent to the ovary, measures about 3.5 cm in length and ranges from 0.4 to 0.6 cm in diameter. Except for the tubo-ovarian adhesions and the attached paratubal cyst, the serosal surface of the fallopian tube is generally smooth, except for a few tiny tan-yellow granularities. Cross sections of the fallopian tube reveal patent lumen that ranges from pinpoint to about 0.2 cm in diameter. The fallopian tube appears grossly free of tumor. A representative portion of the ovarian neoplasm was frozen and sectioned for intraoperative diagnosis (FS #2). Frozen section interpretation was rendered by The frozen section remnant and the rest of the specimen are subsequently fixed in formalin. Representative sections submitted.

B1. Remnant of frozen section #2 (ovarian tumor) - 1

B2. Ovary with tumor - 1

[page 4 of 6]
PATH #:

- B3. Ovary with tumor - 1
- B4. Ovary with tumor - 1
- B5. Ovary with tumor and adherent fallopian tube and paratubal/paraovarian cyst - 1
- B6. Fallopian tube (proximal, mid and distal segments) and paratubal cyst - 3

C. RIGHT ADNEXA

Labeled with the patient's name, labeled "right adnexa", and received in formalin is a salpingo-oophorectomy specimen. The ovary measures 2.0 x 2.0 x 2.0 cm. The serosa is pink-tan, smooth, and lobulated. A previous incision has been made into the specimen in the Operating Room. On section, the ovary has been entirely replaced by pink-tan centrally friable tumor. No evidence of normal ovarian tissue seen. Attached fallopian tube measures 6.0 cm in length x 0.4 cm in diameter and contains a fimbriated end. The serosa is pink-tan, smooth and unremarkable. On section, the fallopian tube contains a 1.0 cm lumen with a wall thickness of not more than 0.3 cm. No gross luminal obstructions are identified. No tumor is identified within the mesovarian tissues. Representative sections are submitted.

C1-C3. Tumor to serosa - 1-4 each

C4. Proximal mid and distal fallopian tube cut on end - 3

D. UTERUS

Labeled with the patient's name, labeled "uterus", and received in formalin is a 40 gram, total hysterectomy specimen with attached vaginal cuff. The uterus is symmetric. The uterus measures about 7.0 cm from the fundus to the ectocervix, 4.0 cm from cornu to cornu, and up to 3.0 cm from the anterior surface to the posterior surface. Attached to the uterus, there are parametrial soft tissues, bilaterally, which measure up to about 0.5 cm in width on the right side and up to 1.0 cm in width on the left side. The parametrial soft tissues appear grossly free of tumor. Attached to the ectocervix, there is about a 1.0 cm long cuff of vaginal tissue, posteriorly. The vaginal mucosa is pink-tan, slightly wrinkled, but otherwise smooth and shows a few punctate hemorrhages. There are tan-yellow soft tissues attached to the vaginal cuff. The soft tissues attached to the vaginal cuff and portions of the muscular wall of vaginal cuff show nodular to plaque-like aggregates of semifirm tan tumor. The cervix is about 3.0 cm long and has a maximum diameter of 2.5 cm in the ectocervical region. The mucosa lining the ectocervix is tan-pink and smooth. The external cervical os is ovoid, about 0.4 cm in diameter and patent. The cervical transformation zone is distinct. The endocervical canal is about 2.0 cm long and lined by tan slightly rugose mucosa. Cut sections of the cervix reveal a few minute to tiny mucus-filled cysts, the largest of which is about 0.2 cm in diameter. The cervix appears grossly free of tumor. The endometrial cavity is about 3.0 cm long and up to 2.0 cm in width. The endometrium is tan to red-tan, ranges from less than 0.1 to about 0.1 cm in thickness and is focally hemorrhagic. No gross pathologic lesions of the endometrium are seen. The muscular uterine wall has a maximum thickness of about 1.5 cm. The myometrium is pink-tan and semifirm. No leiomyomas are identified. No metastatic tumor is seen in the uterus. Representative sections are submitted.

- D1. Anterior cervix - 1
- D2. Anterior lower uterine segment and uppermost endocervix - 1
- D3. Posterior cervix - 1
- D4. Posterior lower uterine segment and upper endocervix - 1
- D5. Anterior uterine fundus - 1
- D6. Anterior uterine corpus - 1
- D7. Anterior lower uterine segment - 1
- D8. Posterior uterine fundus - 1
- D9. Posterior uterine corpus - 1
- D10. Posterior lower uterine segment - 1
- D11. Posterior vaginal cuff and paravaginal soft tissues with tumor - 3
- D12. Posterior vaginal cuff and paravaginal soft tissues with tumor - 3
- D13. Right parametrial soft tissues - multiple
- D14. Left parametrial soft tissues - 2

[page 5 of 6]
PATH #:

E. LEFT SIDE WALL TUMOR

Labeled with the patient's name, labeled "left side wall tumor", and received in formalin is a 3.2 x 2.5 x 1.5 cm portion of tissue, consisting mostly of a nodulocystic aggregate of friable tan soft to semifirm tumor with a small amount of attached yellow fatty tissue. Representative sections are submitted.

E1. 2

F. FALCIFORM

Labeled with the patient's name, labeled "falciform", and received in formalin is a 10.5 x 6.5 x 3.0 cm portion of soft lobulated fatty tissue that appears grossly free of tumor. Representative sections are submitted.

F1. 3

G. OMENTUM (SECOND SPECIMEN)

Labeled with the patient's name, labeled "omentum (second specimen)", and received in formalin are two portions of lobulated omental fat which together measure about 11.0 x 9.0 x 3.0 cm in greatest overall dimensions. Within the omentum, there are two nodular aggregates of metastatic tumor that are each tan-white and firm. One of the tumor nodules measures about 6.0 x 2.0 x 2.0 cm and the second measures about 1.0 x 1.0 x 0.8 cm. A small soft tan nodularity that may represent an omental lymph node is also identified. Recent hemorrhages and adherent blood clot are also noted. Representative sections are submitted.

G1. Omentum with metastatic tumor and possible lymph nodes - 1

G2. Omentum with tumor - 2

G3. Hemorrhagic omentum with adherent blood clot - 1

H. DISTAL PANCREATECTOMY

Labeled with the patient's name, labeled "distal pancreatectomy", and received in formalin is a 280 gram specimen consisting of a small portion of grossly evident pancreatic tissue measuring about 2.5 x 1.5 x 1.5 cm, an entire spleen, which measures about 12.5 x 8.0 x 6.0 cm, and attached perisplenic and peripancreatic soft tissues within which there is a 7.0 x 5.0 x 4.0 cm mass of firm tan-white tumor. The tumor is adherent both to the splenic capsule and to the pancreas. The splenic capsule is tan to brown, and elsewhere shows some fibrous adhesions. Cut sections of the spleen reveal maroon red pulp and intervening tan-white pulp. No invasion of the spleen by tumor is evident. The pancreatic tissue is tan-yellow and the parenchyma of the pancreas appears grossly free of tumor. Representative sections are submitted.

H1. Pancreas and adjacent peripancreatic tumor - 1

H2. Pancreas and adjacent peripancreatic tumor - 1

H3. Spleen and adjacent perisplenic tumor - 1

H4. Uninvolved spleen - 1

I. SEGMENT TRANSVERSE COLON RESECTION

Labeled with the patient's name, labeled "segmental transverse colon resection", and received in formalin are two segments of large intestine. The larger intestinal segment is about 4.5 cm long and has a luminal circumference of 6.5 cm at one resection margin and 7.0 cm at the opposite resection margin. No instructions for orientation are provided. There is no gross evidence of tumor at the resection margins. Attached to the longer intestinal segment, there is relatively abundant focally hemorrhagic yellow mesenteric fat. The mesenteric fat measures up to about 5.0 cm in width. Within the fatty mesentery, there is a 1.7 x 1.5 x 1.5 cm firm tan tumor mass. The tumor does not appear to invade the underlying muscular wall of the intestinal segment. The second smaller segment of large intestine is about 3.0 cm long and has a luminal circumference of 4.0 cm at one resection margin and 5.0 cm at the opposite resection margin. No instructions for orientation are provided. There is no gross evidence of tumor at either resection margin. There is attached pericolic/mesenteric fat that measures up to about 0.5 cm in width attached to the shorter segment of intestine. The pericolic fat serosa, bowel wall and mucosa of the second intestinal segment appear grossly free of tumor. No enlarged lymph nodes are identified in this specimen. Representative sections are submitted.

I1. Proximal and distal margins of longer intestinal segment - 2

I2. Pericolic mesenteric fat attached to longer segment with tumor - 1

I3. Longer segment of colon with attached pericolic fat and tumor abutting the serosal surface - 1

I4. Shorter segment of large intestine and pericolic fat - 2

[page 6 of 6]
PATH #:

J. ILEOCECAL VALVE

Labeled with the patient's name, labeled "ileocecal valve", and received in formalin is a segmental resection including the terminal ileum, ileocecal valve, and right colon. The small intestinal (ileal) segment is about 7.0 cm in length and has a luminal circumference of about 7.0 cm. The ileocecal valve is about 2.0 cm long. The segment of right colon is about 9.0 cm long and has a maximum luminal circumference of about 9.0 cm at the distal resection margin. There is attached peri-intestinal/mesenteric fat measuring up to 4.0 cm in width attached to the small intestine and up to 7.5 cm in width attached to the large intestine. There is no gross evidence of tumor at the proximal (ileal) or distal (colonic) margin of resection. Within the pericolic fat, there is an about 4.0 x 4.0 x 3.0 cm multinodular aggregate of metastatic tumor. The tumor appears to be confined to the pericolic fat, and there is no gross evidence of invasion of the colon by tumor. There is also a smaller (about 0.5 cm in diameter) nodular aggregate of tumor in the pericolic fat. The tumor deposits are tan-white, and semifirm and friable to firm. No vermiform appendix is identified. No regional lymph nodes are evident on gross inspection of the specimen. The mucosal aspects of the terminal ileum, ileocecal valve and cecum are tan and grossly unremarkable. The wall of the terminal ileum measures up to about 0.3 cm in thickness where that of the colon is about 0.6 cm in maximal thickness. No invasion of the wall of either the small or large intestine is identified.

Representative sections are submitted.

- J1. Proximal (ileal) resection margin - 1
- J2. Distal (colonic) resection margin - 1
- J3. Small intestine - 1
- J4. Colon and pericolic tissues with tumor - 1
- J5. Pericolic fat with tumor - 1
- J6. Small nodule of tumor in pericolic fat - 1

K. RECTOSIGMOID EPIPLOICA

Labeled with the patient's name, labeled "rectosigmoid epiploica", and received in formalin is a 3.0 x 3.0 x 1.0 cm aggregate of multiple fragments of tan-yellow fibroadipose tissue, within which there are nodular deposits of firm to semifirm tan-white tumor. The tumor nodules range from about 0.3 to 0.5 cm in maximum dimension.

Representative sections are submitted.

- K1. Multiple
- K2. 1

Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

SPECIMENS A AND B:

- Consistent with mullerian carcinoma

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

SPECIMEN [C], UTERUS:

- No gross tumor

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed

Source: NCI Genomic Data Commons file 5395983e-2c1e-49d2-8039-0fff7b7bd0eb (TCGA-23-1030.E44D825F-89EE-4FF7-B6D6-B0B17E305B2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).